Somatic mutation profile of tumor specimen C3N-00317-02 (aliquot CPT0012260012) from CPTAC case C3N-00317, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.2 years (27,092 days).
Specimen C3N-00317-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8376946-27df-427e-a328-78d109bef9ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00317-31 (Blood Derived Normal), aliquot CPT0012350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32126c0a-9653-4ba2-840b-f654a826b514

The open-access MAF lists 122 somatic variants for this specimen: 75 protein-altering or splice-affecting, 33 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 33, Frame Shift Del 9, Intron 5, 5'UTR 4, Splice Site 3, Frame Shift Ins 2, RNA 2, 3'UTR 2, 5'Flank 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPT4 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs963850145, COSV67921254; called by muse, mutect2, varscan2
- ASZ1 | c.927G>T p.R309S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV104372636; called by muse, mutect2
- ATRX | c.3238A>G p.K1080E | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.265); catalogued as COSV64872241; called by muse, mutect2
- ATXN3L | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1555931850; called by muse, mutect2, varscan2
- BAP1 | c.546_547insT p.L183Sfs*10 | Frame Shift Ins (INS) | VAF 88/405 reads (22%) | catalogued as COSV56231810; called by mutect2, pindel, varscan2
- BCAS1 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 166/535 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs749019655, COSV65083668, COSV65083914; called by muse, mutect2, varscan2
- GATA3 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60519299, COSV60521231; called by muse, mutect2, varscan2
- GNAT3 | c.701T>A p.L234H | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68068507; called by muse, mutect2, varscan2
- LRRC71 | c.1637A>T p.K546M | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746573089; called by muse, mutect2, varscan2
- POLA1 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1317456378; called by muse, mutect2, varscan2
- POLD1 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs372190244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHBDL3 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747341218; called by muse, mutect2, varscan2
- RP1L1 | c.4699C>T p.R1567C | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762676280, COSV101222955; called by muse, mutect2, varscan2
- SEPTIN1 | c.446+2T>C p.X149_splice (on ENST00000321367; = p.X102_splice on NM_052838.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 43/156 reads (28%) | catalogued as rs1328616004; called by muse, mutect2, varscan2
- SERPINE2 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99296786; called by muse, mutect2, varscan2
- SIGLEC8 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.929); catalogued as rs368238857, COSV100367361; called by muse, mutect2, varscan2
- TBC1D9B | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV62281984; called by muse, mutect2, varscan2
- TJP3 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as rs755131245; called by muse, mutect2, varscan2
- TMEM168 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs111844937; called by muse, mutect2, varscan2
- TRNAU1AP | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs753016583; called by muse, mutect2, varscan2
- USP24 | c.6260C>A p.P2087Q | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.656); catalogued as COSV53775525; called by muse, mutect2, varscan2
- ALPK1 | c.148del p.L50* | Frame Shift Del (DEL) | VAF 39/202 reads (19%) | called by mutect2, pindel, varscan2
- ARID5A | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARID5A | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ATXN3 | c.23A>T p.K8I | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- BRD8 | c.1717A>T p.N573Y (on ENST00000254900 / NM_139199.2; = p.N646Y on NM_006696.4) | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C8B | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC106 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC15 | c.1596dup p.L533Sfs*3 | Frame Shift Ins (INS) | VAF 51/312 reads (16%) | called by mutect2, pindel, varscan2
- CDK5R2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.192); called by muse, mutect2
- CHD3 | c.1378C>G p.R460G | Missense Mutation (SNP) | VAF 61/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHD6 | c.6155_6164del p.E2052Afs*42 | Frame Shift Del (DEL) | VAF 28/205 reads (14%) | called by mutect2, pindel, varscan2
- CNP | c.146G>C p.C49S | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN5 | c.2929G>A p.A977T | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- COL4A4 | c.3676C>A p.R1226S | Missense Mutation (SNP) | VAF 47/427 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CR1 | c.3555A>C p.K1185N | Missense Mutation (SNP) | VAF 91/452 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- EMC1 | c.1334G>C p.R445P | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENOSF1 | c.1269_1288del p.D423Efs*37 (on ENST00000340116 / NM_001354066.2; = p.D389Efs*37 on NM_017512.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/164 reads (10%) | called by mutect2, pindel
- FIBCD1 | c.1145A>T p.H382L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FNDC3A | c.1508del p.L503* (on ENST00000492622 / NM_001079673.2; = p.L447* on NM_014923.5) | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.3325G>A p.V1109M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by mutect2, varscan2
- FXR2 | c.812C>G p.T271S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIAA0100 | c.3560A>C p.D1187A | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- LAMA2 | c.4655C>T p.A1552V | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MEGF10 | c.916C>A p.R306= | Splice Region (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- MYOF | c.3841A>T p.I1281F | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- NCF1 | c.1009del p.R337Afs*39 | Frame Shift Del (DEL) | VAF 62/459 reads (14%) | called by mutect2, varscan2
- NECAB2 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5L2 | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PARP15 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- PARP15 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PATL1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PHIP | c.3936A>C p.R1312S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PHYKPL | c.916T>G p.Y306D | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- PKD1 | c.4577G>C p.R1526T | Missense Mutation (SNP) | VAF 114/367 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PLAC8 | c.137G>C p.C46S | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PRDM16 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRSS3 | c.25G>C p.A9P (on ENST00000361005 / NM_007343.4; = p.A117P on NM_002771.3) | Missense Mutation (SNP) | VAF 96/726 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- PSMD14 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RANBP2 | c.7200A>T p.R2400S | Missense Mutation (SNP) | VAF 42/700 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- RAPH1 | c.2456del p.F819Sfs*44 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- RGPD4 | c.4275A>T p.R1425S | Missense Mutation (SNP) | VAF 44/430 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2
- RGS22 | c.3510del p.K1170Nfs*28 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- SART3 | c.2904G>T p.K968N (on ENST00000228284; = p.K950N on NM_014706.4) | Missense Mutation (SNP) | VAF 87/475 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SERGEF | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SMAD6 | c.42del p.W14Cfs*50 | Frame Shift Del (DEL) | VAF 26/146 reads (18%) | called by pindel, varscan2
- SNRPB2 | c.65-1G>A p.X22_splice | Splice Site (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- TENT4A | c.1009-1G>A p.X337_splice | Splice Site (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- TNRC18 | c.7353_7357delinsCG p.R2452_R2453delinsG | In Frame Del (DEL) | VAF 25/121 reads (21%) | called by pindel, varscan2*
- TRPC4 | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TULP4 | c.2827C>A p.L943M | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VHL | c.598_599del p.R200Afs*55 | Frame Shift Del (DEL) | VAF 81/363 reads (22%) | called by mutect2, pindel, varscan2
- ZFAT | c.2969C>T p.S990F | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF525 | c.230A>C p.H77P | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZSWIM3 | c.632C>G p.T211S | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.4611G>A p.K1537= | Silent (SNP) | VAF 86/548 reads (16%) | called by muse, mutect2, varscan2
- CNNM2 | c.915C>T p.I305= | Silent (SNP) | VAF 142/693 reads (20%) | catalogued as rs371599593, COSV63995689; called by muse, mutect2, varscan2
- CREB5 | c.330G>C p.T110= (on ENST00000357727 / NM_182898.4; = p.T103= on NM_004904.3) | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV63217858; called by muse, mutect2, varscan2
- CTNNA3 | c.1992A>G p.Q664= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2
- CYP51A1 | c.261A>C p.P87= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- DDR2 | c.978C>T p.D326= | Silent (SNP) | VAF 84/511 reads (16%) | catalogued as rs766364700, COSV63375272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMBT1 | c.156G>A p.S52= | Silent (SNP) | VAF 33/254 reads (13%) | catalogued as rs779781646, COSV57561509; called by muse, mutect2
- DMRTA2 | c.7C>T p.L3= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- GATA3 | c.1098A>T p.R366= | Silent (SNP) | VAF 51/331 reads (15%) | catalogued as rs755075472; called by muse, mutect2, varscan2
- HDAC1 | c.1161C>T p.D387= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs757896216; called by muse, mutect2, varscan2
- HS3ST4 | c.474G>A p.E158= | Silent (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2
- HTR1E | c.624G>C p.A208= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV59508553; called by muse, mutect2, varscan2
- INSM1 | c.582C>T p.A194= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- LCORL | c.1251A>C p.L417= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- LDLR | c.2319C>T p.G773= | Silent (SNP) | VAF 81/404 reads (20%) | catalogued as rs377563758; ClinVar: likely benign; called by muse, varscan2
- MAPKAPK3 | c.381C>T p.F127= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as rs534053112; called by muse, mutect2, varscan2
- MYO15B | c.7731C>G p.S2577= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- NPY4R | c.582C>T p.F194= | Silent (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- OR7G3 | c.642C>A p.I214= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as rs375002810, COSV59640152; called by muse, mutect2, varscan2
- PCLO | c.10143T>C p.V3381= | Silent (SNP) | VAF 130/290 reads (45%) | called by muse, mutect2, varscan2
- PHF7 | c.828C>T p.C276= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs1158952346; called by muse, mutect2, varscan2
- PIWIL4 | c.1206G>A p.K402= | Silent (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2
- PMPCB | c.1443C>A p.R481= | Silent (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.123G>A p.A41= | Silent (SNP) | VAF 76/262 reads (29%) | called by muse, mutect2, varscan2
- RPL18A | c.420G>A p.P140= | Silent (SNP) | VAF 39/197 reads (20%) | catalogued as rs772177229; called by muse, mutect2, varscan2
- RSPH10B | c.1893T>A p.A631= | Silent (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- SP4 | c.1986T>C p.S662= | Silent (SNP) | VAF 45/203 reads (22%) | called by muse, mutect2, varscan2
- TMEM61 | c.132C>T p.T44= | Silent (SNP) | VAF 43/266 reads (16%) | catalogued as rs778412005; called by muse, mutect2, varscan2
- TP53TG3D | c.159G>A p.S53= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs1261053548; called by mutect2, varscan2
- TSPAN10 | c.888C>T p.C296= (on ENST00000574882 / NM_001290212.1; = p.C258= on NM_031945.4) | Silent (SNP) | VAF 16/514 reads (3%) | catalogued as rs1373975472, COSV58507520; called by muse, mutect2
- UBP1 | c.960T>C p.Y320= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs1559674373; called by muse, mutect2, varscan2
- UGT1A7 | c.171A>G p.V57= | Silent (SNP) | VAF 47/230 reads (20%) | called by muse, mutect2, varscan2
- YWHAZ | c.90T>A p.T30= | Silent (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- CD2 | c.-5C>T | 5'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- CFAP20DC | c.2332+54T>A | Intron (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2
- ERCC6 | c.1397+7607A>G | Intron (SNP) | VAF 46/177 reads (26%) | called by muse, mutect2, varscan2
- FCRLB | c.-6T>C | 5'UTR (SNP) | VAF 29/155 reads (19%) | called by muse, mutect2, varscan2
- GPHN | c.-849A>G | 5'UTR (SNP) | VAF 44/226 reads (19%) | called by muse, mutect2, varscan2
- GPHN | c.1314+25T>A | Intron (SNP) | VAF 41/244 reads (17%) | called by muse, mutect2, varscan2
- JAZF1-AS1 | n.807del | RNA (DEL) | VAF 25/214 reads (12%) | called by mutect2, pindel, varscan2
- LAT | c.163+21C>A | Intron (SNP) | VAF 33/160 reads (21%) | called by muse, mutect2, varscan2
- PLK1 | c.*129C>T | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- RGPD3 | c.-12G>C | 5'UTR (SNP) | VAF 94/398 reads (24%) | catalogued as COSV100449858; called by muse, mutect2
- SH3KBP1 | c.726+12932G>C | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- SNORD114-24 | n.49C>G | RNA (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- TNNT2 | chr1:201377626 A>G | 5'Flank (SNP) | VAF 56/358 reads (16%) | called by muse, mutect2, varscan2
- XBP1 | c.*263C>T | 3'UTR (SNP) | VAF 17/80 reads (21%) | catalogued as rs751977462, COSV53273909; called by muse, mutect2, varscan2
